Somatic mutation profile of tumor specimen TCGA-XR-A8TD-01A (aliquot TCGA-XR-A8TD-01A-12D-A38X-10) from TCGA case TCGA-XR-A8TD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 49.0 years (17,908 days).
Specimen TCGA-XR-A8TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 754562e0-3ca5-4ff0-be9b-f795e9598a44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XR-A8TD-10A (Blood Derived Normal), aliquot TCGA-XR-A8TD-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f74f3bd-697f-4fa7-a866-15ba48c97c00

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.1733G>T p.C578F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695622; called by muse, mutect2, varscan2
- ADGRB3 | c.3829T>A p.L1277M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99485335; called by muse, mutect2, varscan2
- AJAP1 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100981792; called by muse, mutect2, varscan2
- ANKFN1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100593554; called by muse, mutect2, varscan2
- ANKRD7 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.402); catalogued as COSV54554039, COSV99501169; called by muse, mutect2, varscan2
- ARFGEF1 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99142503; called by muse, mutect2, varscan2
- ARID2 | c.4922A>C p.K1641T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV100536287; called by muse, mutect2, varscan2
- C12orf40 | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61138174; called by muse, mutect2, varscan2
- CABIN1 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs193920999, COSV54079534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC178 | c.1221A>C p.Q407H | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV100285046, COSV55783142; called by muse, mutect2, varscan2
- CCNA2 | c.387T>G p.N129K | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV99144954; called by muse, mutect2, varscan2
- CFAP47 | c.1900C>T p.H634Y | Missense Mutation (SNP) | VAF 162/766 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs17852470, COSV99935119; called by muse, mutect2
- CLPX | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as rs780719008, COSV100269503, COSV100269716; called by muse, mutect2, varscan2
- COL5A3 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99318972; called by muse, mutect2, varscan2
- EIF2AK4 | c.1582T>G p.W528G | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99774755; called by muse, mutect2, varscan2
- EIF2AK4 | c.1583G>T p.W528L | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99774767; called by muse, mutect2, varscan2
- EPHA7 | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100993817, COSV65189477; called by muse, mutect2, varscan2
- EYS | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100676535; called by muse, mutect2, varscan2
- GALNTL6 | c.741C>G p.N247K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV101560296; called by muse, mutect2, varscan2
- GLI3 | c.2962G>A p.G988R | Missense Mutation (SNP) | VAF 151/637 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs765236732, COSV101229894; called by muse, mutect2, varscan2
- GPER1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1179693461, COSV99867029; called by muse, mutect2, varscan2
- HUWE1 | c.8751C>A p.S2917R | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99472534, COSV99474080; called by muse, mutect2, varscan2
- KIAA1217 | c.3019A>T p.M1007L | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as COSV100286694; called by muse, mutect2, varscan2
- MAP3K11 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1246742554, COSV100482538; called by muse, mutect2, varscan2
- MED13 | c.6310G>T p.V2104L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101181107, COSV67266178; called by muse, mutect2, varscan2
- NAV3 | c.4815C>A p.S1605R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV99891499; called by muse, mutect2, varscan2
- NCKAP1L | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV53210038; called by muse, mutect2, varscan2
- NLGN1 | c.1864T>G p.Y622D | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100849415; called by muse, mutect2, varscan2
- OCLN | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV100783826; called by muse, mutect2, varscan2
- OR10R2 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.206); catalogued as COSV100936795, COSV63769138; called by muse, mutect2, varscan2
- OR51L1 | c.581C>G p.A194G | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV100386439, COSV58625470; called by muse, mutect2
- OR52W1 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV60951218; called by muse, mutect2, varscan2
- RGS13 | c.64A>G p.N22D | Missense Mutation (SNP) | VAF 243/692 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101232217; called by muse, mutect2, varscan2
- SLC7A3 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV99979568; called by muse, mutect2, varscan2
- SLPI | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); catalogued as COSV100619761; called by muse, mutect2, varscan2
- SPATA17 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 80/433 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100861161, COSV65122240; called by muse, mutect2, varscan2
- SPOCK3 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100693078; called by mutect2, varscan2
- THADA | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 38/163 reads (23%) | catalogued as COSV100368714; called by muse, mutect2, varscan2
- USP38 | c.2345A>G p.D782G | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100189272; called by muse, mutect2, varscan2
- WDR7 | c.4183G>A p.G1395R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99589550; called by muse, mutect2, varscan2
- ZDHHC12 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.098); catalogued as COSV99403645; called by muse, mutect2, varscan2
- ZNF536 | c.3896-2A>T p.X1299_splice | Splice Site (SNP) | VAF 38/156 reads (24%) | catalogued as COSV62834928; called by muse, mutect2, varscan2
- ZNF76 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99987704; called by muse, mutect2, varscan2
- ZNF880 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV101424928, COSV101424981; called by muse, mutect2, varscan2
- CDKN1A | c.222del p.K75Sfs*73 | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- LGI3 | c.26dup p.P12Afs*20 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- ACP3 | c.627C>A p.V209= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100313390; called by muse, mutect2, varscan2
- AKAP1 | c.60C>T p.L20= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs867529780, COSV100027684, COSV58471247; called by muse, mutect2, varscan2
- CCDC136 | c.2823T>C p.D941= | Silent (SNP) | VAF 54/256 reads (21%) | catalogued as COSV99922669; called by muse, mutect2, varscan2
- DGKD | c.1389C>T p.T463= (on ENST00000264057 / NM_152879.3; = p.T419= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs767446963, COSV99896445; called by muse, mutect2, varscan2
- ICE1 | c.3681A>G p.E1227= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as COSV99664857; called by muse, mutect2, varscan2
- IFNA4 | c.471G>A p.K157= | Silent (SNP) | VAF 34/233 reads (15%) | catalogued as COSV101427062; called by muse, mutect2, varscan2
- MAPKAP1 | c.60C>T p.T20= | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV99785058; called by muse, mutect2, varscan2
- PCDHA3 | c.1638C>A p.G546= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63545125; called by muse, mutect2, varscan2
- SALL3 | c.1083G>A p.P361= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs377646222; called by muse, mutect2, varscan2
- SIGLEC1 | c.888C>T p.A296= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99165905; called by muse, mutect2, varscan2
- SYTL5 | c.256C>T p.L86= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV99937298; called by muse, mutect2, varscan2
- THADA | c.1278G>T p.V426= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as COSV100368720; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1320T>G p.T440= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99648646; called by muse, mutect2, varscan2
- ZNF549 | c.582C>T p.I194= (on ENST00000376233 / NM_001199295.2; = p.I181= on NM_153263.2) | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as COSV99558588; called by muse, mutect2, varscan2
